Somatic mutation profile of tumor specimen TARGET-40-PATPBS-01A (aliquot TARGET-40-PATPBS-01A-01D) from TARGET case TARGET-40-PATPBS, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 15.1 years (5,513 days).
Specimen TARGET-40-PATPBS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e55d73af-32fd-4e9f-843a-94f1b402bc49.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PATPBS-10A (Blood Derived Normal), aliquot TARGET-40-PATPBS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f6a8a39-5ed5-47e4-81aa-9fcb943d050d

The open-access MAF lists 87 somatic variants for this specimen: 47 protein-altering or splice-affecting, 19 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 19, RNA 7, Intron 7, 5'UTR 3, 3'UTR 3, Frame Shift Del 2, Nonsense Mutation 2, Splice Site 2, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 168/303 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACAD11 | c.2090C>A p.T697N | Missense Mutation (SNP) | VAF 53/396 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.724); catalogued as rs78134968; called by muse, mutect2, varscan2
- COL16A1 | c.1219G>A p.G407R | Missense Mutation (SNP) | VAF 441/837 reads (53%) | SIFT tolerated (0.58); PolyPhen benign (0.273); catalogued as rs200545130, COSV54713714; called by muse, mutect2, varscan2
- CYB5RL | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 47/287 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV55276526; called by muse, mutect2, varscan2
- E2F7 | c.6G>C p.E2D | Missense Mutation (SNP) | VAF 98/314 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as COSV100523573; called by muse, mutect2, varscan2
- KCNS3 | c.806C>T p.T269M | Missense Mutation (SNP) | VAF 18/628 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1380663454; called by muse, mutect2
- MUC16 | c.40531C>A p.L13511I | Missense Mutation (SNP) | VAF 513/886 reads (58%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.977); catalogued as COSV66692184; called by muse, mutect2, varscan2
- PUS7 | c.1981C>T p.R661C | Missense Mutation (SNP) | VAF 58/784 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs776732227, COSV62675630; called by muse, mutect2
- TEDC2 | c.190C>G p.L64V | Missense Mutation (SNP) | VAF 19/270 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV99563746; called by muse, mutect2
- TGM2 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 88/533 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs780697822; called by muse, mutect2, varscan2
- TRRAP | c.3509G>A p.R1170Q | Missense Mutation (SNP) | VAF 33/540 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs1554412673, COSV100722149; called by muse, mutect2
- ADAMTS10 | c.744C>G p.D248E | Missense Mutation (SNP) | VAF 46/908 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2
- B3GALT5 | c.15G>C p.K5N | Missense Mutation (SNP) | VAF 37/591 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); called by muse, mutect2
- BTBD8 | c.1469T>A p.L490Q | Missense Mutation (SNP) | VAF 47/737 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- CAMSAP2 | c.172T>C p.Y58H | Missense Mutation (SNP) | VAF 23/783 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CRP | c.38T>C p.L13P | Missense Mutation (SNP) | VAF 115/453 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CSMD1 | c.2090A>G p.E697G (on ENST00000520002; = p.E696G on NM_033225.6) | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- DUSP21 | c.206T>A p.I69K | Missense Mutation (SNP) | VAF 52/554 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.215); called by muse, mutect2
- EN1 | c.976dup p.R326Pfs*149 | Frame Shift Ins (INS) | VAF 48/138 reads (35%) | called by mutect2, pindel, varscan2
- FEZF1 | c.97A>T p.I33F | Missense Mutation (SNP) | VAF 66/829 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- FGA | c.966A>T p.K322N | Missense Mutation (SNP) | VAF 30/594 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- HERC1 | c.7502C>T p.S2501L | Missense Mutation (SNP) | VAF 58/468 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- KIAA2012 | c.256A>G p.K86E | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- KIF19 | c.1389-1G>C p.X463_splice | Splice Site (SNP) | VAF 186/256 reads (73%) | called by muse, mutect2
- LAMA1 | c.5213A>G p.K1738R | Missense Mutation (SNP) | VAF 120/299 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- LIPI | c.718C>A p.Q240K | Missense Mutation (SNP) | VAF 84/390 reads (22%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2, varscan2
- MRPL43 | c.592T>G p.S198A | Missense Mutation (SNP) | VAF 51/443 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH9 | c.5204A>G p.E1735G | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- NCOA5 | c.530G>A p.R177K | Missense Mutation (SNP) | VAF 32/418 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- NPHP4 | c.1180T>C p.W394R | Missense Mutation (SNP) | VAF 376/729 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OAS2 | c.1555G>C p.E519Q | Missense Mutation (SNP) | VAF 48/594 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PLXNA4 | c.171_183del p.E58Tfs*17 | Frame Shift Del (DEL) | VAF 67/434 reads (15%) | called by mutect2, pindel, varscan2
- PREX2 | c.1271A>G p.E424G | Missense Mutation (SNP) | VAF 77/511 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RYR1 | c.9445C>T p.Q3149* | Nonsense Mutation (SNP) | VAF 48/549 reads (9%) | called by muse, mutect2
- SEC61A2 | c.648_653delinsC p.H218Vfs*45 | Frame Shift Del (DEL) | VAF 110/208 reads (53%) | called by pindel, varscan2*
- SHANK2 | c.4477G>T p.E1493* | Nonsense Mutation (SNP) | VAF 36/456 reads (8%) | called by muse, mutect2
- SNX19 | c.2847-2A>T p.X949_splice | Splice Site (SNP) | VAF 141/241 reads (59%) | called by muse, mutect2, varscan2
- SRD5A3 | c.575G>A p.G192E | Missense Mutation (SNP) | VAF 42/390 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); called by muse, mutect2
- SRP19 | c.176A>G p.N59S | Missense Mutation (SNP) | VAF 141/311 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- STT3B | c.1969G>T p.V657F | Missense Mutation (SNP) | VAF 197/296 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- TNFRSF8 | c.325C>G p.R109G | Missense Mutation (SNP) | VAF 58/327 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- TRPV3 | c.318G>C p.Q106H | Missense Mutation (SNP) | VAF 139/514 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- TSGA10IP | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 30/386 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); called by muse, mutect2
- UHRF1BP1L | c.512A>T p.D171V | Missense Mutation (SNP) | VAF 125/180 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- USHBP1 | c.1960C>A p.Q654K | Missense Mutation (SNP) | VAF 359/676 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, varscan2
- VWA8 | c.3077C>G p.P1026R | Missense Mutation (SNP) | VAF 27/410 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- ZDHHC5 | c.1451C>T p.S484L | Missense Mutation (SNP) | VAF 17/465 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.306); called by muse, mutect2
- AKAP1 | c.201A>G p.V67= | Silent (SNP) | VAF 26/245 reads (11%) | called by muse, mutect2, varscan2
- CD2BP2 | c.756T>G p.A252= | Silent (SNP) | VAF 216/309 reads (70%) | called by muse, mutect2, varscan2
- CNTFR | c.798C>A p.T266= | Silent (SNP) | VAF 291/725 reads (40%) | called by muse, mutect2, varscan2
- CNTN5 | c.711C>A p.S237= | Silent (SNP) | VAF 40/851 reads (5%) | catalogued as COSV54275477; called by muse, mutect2
- COL15A1 | c.489C>A p.R163= | Silent (SNP) | VAF 76/990 reads (8%) | called by muse, mutect2
- EFNA1 | c.126G>A p.Q42= | Silent (SNP) | VAF 31/702 reads (4%) | called by muse, mutect2
- MIP | c.84G>T p.L28= | Silent (SNP) | VAF 149/522 reads (29%) | catalogued as rs368415438; called by muse, mutect2, varscan2
- NEK6 | c.21C>T p.H7= | Silent (SNP) | VAF 34/350 reads (10%) | called by muse, mutect2
- NSD3 | c.33C>T p.I11= | Silent (SNP) | VAF 50/613 reads (8%) | called by muse, mutect2
- OR10A5 | c.717C>T p.F239= | Silent (SNP) | VAF 182/635 reads (29%) | catalogued as rs781595834, COSV100203364, COSV55055055; called by muse, mutect2, varscan2
- OR10A7 | c.297C>G p.T99= | Silent (SNP) | VAF 22/644 reads (3%) | called by muse, mutect2
- PCSK6 | c.2208C>G p.G736= | Silent (SNP) | VAF 113/254 reads (44%) | called by muse, mutect2, varscan2
- PLAGL2 | c.189A>G p.P63= | Silent (SNP) | VAF 98/558 reads (18%) | called by muse, mutect2, varscan2
- PLEKHM1 | c.1479G>A p.A493= | Silent (SNP) | VAF 15/149 reads (10%) | catalogued as rs371968983; called by muse, mutect2
- PRR22 | c.1248C>T p.D416= | Silent (SNP) | VAF 73/126 reads (58%) | called by muse, mutect2, varscan2
- RIMS1 | c.1905C>T p.I635= | Silent (SNP) | VAF 49/438 reads (11%) | called by muse, mutect2, varscan2
- SIPA1L1 | c.3366A>G p.L1122= | Silent (SNP) | VAF 93/394 reads (24%) | called by muse, mutect2, varscan2
- ZNF362 | c.375G>A p.P125= | Silent (SNP) | VAF 109/347 reads (31%) | catalogued as rs762428848, COSV65031939; called by muse, mutect2, varscan2
- ZNF44 | c.507C>T p.Y169= (on ENST00000356109 / NM_001164276.2; = p.Y121= on NM_016264.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 94/1490 reads (6%) | called by muse, mutect2
- ACOXL | c.*34G>A | 3'UTR (SNP) | VAF 51/177 reads (29%) | called by muse, mutect2, varscan2
- ANAPC5 | c.1745+27G>C | Intron (SNP) | VAF 10/250 reads (4%) | called by muse, mutect2
- ARHGEF34P | n.1444A>G | RNA (SNP) | VAF 195/1479 reads (13%) | called by muse, mutect2, varscan2
- ATRN | c.*10C>T | 3'UTR (SNP) | VAF 46/152 reads (30%) | called by muse, mutect2, varscan2
- CDC42 | chr1:22025082 G>A | 5'Flank (SNP) | VAF 65/247 reads (26%) | called by muse, mutect2, varscan2
- CEACAM5 | c.703+85T>C | Intron (SNP) | VAF 18/111 reads (16%) | called by muse, mutect2, varscan2
- CYP51A1 | c.-33C>T | 5'UTR (SNP) | VAF 37/79 reads (47%) | called by muse, varscan2
- DAOA | c.282-118T>C | Intron (SNP) | VAF 18/164 reads (11%) | called by mutect2, varscan2
- DMD | c.31+83091T>A | Intron (SNP) | VAF 50/216 reads (23%) | called by muse, mutect2, varscan2
- FAM110A | c.-98+3529G>C | Intron (SNP) | VAF 38/316 reads (12%) | called by muse, mutect2
- LILRP1 | n.464C>A | RNA (SNP) | VAF 10/197 reads (5%) | called by muse, mutect2
- OR2U1P | n.633T>C | RNA (SNP) | VAF 53/262 reads (20%) | called by muse, mutect2, varscan2
- PDE11A | c.-68G>A | 5'UTR (SNP) | VAF 26/92 reads (28%) | called by muse, mutect2, varscan2
- PHLDB3 | c.1250-19C>A | Intron (SNP) | VAF 53/99 reads (54%) | called by muse, mutect2, varscan2
- SLC22A17 | n.1302G>A | RNA (SNP) | VAF 54/917 reads (6%) | catalogued as rs775898371, COSV99249077; called by muse, mutect2
- SSX6P | n.148C>G | RNA (SNP) | VAF 55/560 reads (10%) | called by muse, mutect2, varscan2
- SSX6P | n.149C>A | RNA (SNP) | VAF 55/571 reads (10%) | called by muse, mutect2, varscan2
- TDH | n.462C>A | RNA (SNP) | VAF 14/100 reads (14%) | called by muse, mutect2
- TIPRL | c.-5C>T | 5'UTR (SNP) | VAF 85/504 reads (17%) | called by muse, mutect2, varscan2
- ZMIZ2 | c.1385+29C>G | Intron (SNP) | VAF 52/716 reads (7%) | called by muse, mutect2
- ZSWIM8 | c.*65G>C | 3'UTR (SNP) | VAF 14/101 reads (14%) | catalogued as rs781302362; called by muse, mutect2
